Somatic mutation profile of tumor specimen TCGA-DD-AACL-01A (aliquot TCGA-DD-AACL-01A-11D-A40R-10) from TCGA case TCGA-DD-AACL, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 66.7 years (24,355 days).
Specimen TCGA-DD-AACL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc5b52f1-c46d-47aa-8d52-591c83d1a336.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AACL-10A (Blood Derived Normal), aliquot TCGA-DD-AACL-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b55293be-40e2-4af3-b76e-b05604e08367

The open-access MAF lists 346 somatic variants for this specimen: 255 protein-altering or splice-affecting, 84 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 209, Silent 84, Nonsense Mutation 23, Splice Site 9, Splice Region 6, Frame Shift Del 4, Intron 3, RNA 2, Frame Shift Ins 2, In Frame Del 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.712T>C p.C238R | Missense Mutation (SNP) | VAF 23/57 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519981, CM025271, CM056070, COSV52699956, COSV52707471, COSV52711035, COSV52711932; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.5263A>T p.I1755F (on ENST00000272895 / NM_173076.3; = p.I1437F on NM_015657.3) | Missense Mutation (SNP) | VAF 58/190 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV55979932; called by muse, mutect2, varscan2
- ABCA13 | c.13543G>C p.V4515L | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as rs767565751, COSV101291288, COSV68942905; called by muse, mutect2, varscan2
- ADAMTS14 | c.155T>A p.F52Y | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.217); catalogued as COSV100941499; called by muse, mutect2, varscan2
- ADCY2 | c.1295T>A p.L432Q | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100602508; called by muse, mutect2, varscan2
- ADGRE5 | c.517A>T p.S173C | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); catalogued as COSV99662833; called by muse, mutect2, varscan2
- ADGRL2 | c.4192A>T p.R1398W (on ENST00000370717 / NM_001366005.1; = p.R1342W on NM_012302.4) | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV99588241; called by muse, mutect2, varscan2
- AGAP2 | c.1482T>A p.H494Q (on ENST00000547588 / NM_001122772.2; = p.H158Q on NM_014770.4) | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as COSV99222809; called by muse, mutect2, varscan2
- AGTPBP1 | c.1992A>T p.L664F (on ENST00000357081 / NM_001330701.2; = p.L624F on NM_015239.2) | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); catalogued as COSV100429604; called by muse, mutect2, varscan2
- AL139300.1 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 7/37 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99914801; called by muse, mutect2, varscan2
- ANKK1 | c.2275C>A p.P759T | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as COSV100392785; called by muse, mutect2, varscan2
- ARHGAP30 | c.584T>A p.M195K | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as COSV100920202; called by muse, mutect2, varscan2
- ARHGAP31 | c.2933T>A p.L978H | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99956918; called by muse, mutect2, varscan2
- ARHGEF17 | c.3622A>T p.K1208* | Nonsense Mutation (SNP) | VAF 15/72 reads (21%) | catalogued as COSV99735314; called by muse, mutect2, varscan2
- ASB16 | c.308G>C p.W103S | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99518814; called by muse, mutect2, varscan2
- ATP10D | c.1635+2T>C p.X545_splice | Splice Site (SNP) | VAF 10/85 reads (12%) | catalogued as rs1408353811, COSV99905465; called by muse, mutect2, varscan2
- ATP13A1 | c.1187C>T p.P396L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as COSV99366003; called by muse, mutect2, varscan2
- BBS7 | c.88A>T p.R30* | Nonsense Mutation (SNP) | VAF 26/85 reads (31%) | catalogued as CD144741, COSV99144876; called by muse, mutect2, varscan2
- BCAR3 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs140733181; called by muse, mutect2
- BRPF1 | c.2104A>T p.S702C | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV100121192; called by muse, mutect2, varscan2
- BTRC | c.1506A>T p.L502F (on ENST00000370187 / NM_033637.4; = p.L466F on NM_003939.5) | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100927783; called by muse, mutect2, varscan2
- C6orf118 | c.563A>T p.Q188L | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as COSV100024330; called by muse, mutect2, varscan2
- CACNA1C | c.6506T>A p.V2169E (on ENST00000399634 / NM_001167625.1; = p.V2098E on NM_000719.7) | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as COSV100217684; called by muse, mutect2, varscan2
- CACNA1F | c.4231A>T p.T1411S | Missense Mutation (SNP) | VAF 83/380 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.111); catalogued as COSV100544640; called by muse, mutect2, varscan2
- CCDC60 | c.1636T>A p.Y546N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV100554927; called by muse, mutect2, varscan2
- CCDC92 | c.127A>T p.S43C | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as COSV99435431; called by muse, mutect2, varscan2
- CCN2 | c.781A>T p.K261* | Nonsense Mutation (SNP) | VAF 18/88 reads (20%) | catalogued as COSV100915297, COSV63466573; called by muse, mutect2, varscan2
- CCN5 | c.674T>A p.L225Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99509264; called by muse, mutect2, varscan2
- CD44 | c.1109A>T p.H370L | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV99555644; called by muse, mutect2, varscan2
- CDH18 | c.1779A>C p.R593S | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99933732; called by muse, mutect2, varscan2
- CDH19 | c.2287A>T p.M763L | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.021); catalogued as COSV100051341; called by muse, mutect2
- CDH19 | c.2285G>T p.C762F | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV100051343; called by muse, mutect2
- CDH20 | c.1841C>T p.P614L | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as COSV99405006; called by muse, mutect2, varscan2
- CDHR3 | c.1126A>T p.S376C | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.527); catalogued as COSV100488199; called by muse, mutect2, varscan2
- CDKL5 | c.629T>C p.L210S | Missense Mutation (SNP) | VAF 49/212 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV101184234; called by muse, mutect2, varscan2
- CEACAM4 | c.320T>A p.L107Q | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99701007; called by muse, mutect2, varscan2
- CHST10 | c.56T>C p.M19T | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.165); catalogued as COSV99958858; called by muse, mutect2, varscan2
- CKAP5 | c.1301A>T p.K434M | Missense Mutation (SNP) | VAF 51/267 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100370674; called by muse, mutect2, varscan2
- CLCN4 | c.499G>C p.A167P | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101073760; called by muse, mutect2, varscan2
- COBL | c.121dup p.H41Pfs*31 | Frame Shift Ins (INS) | VAF 27/143 reads (19%) | catalogued as rs778516787; called by mutect2, varscan2
- COG7 | c.1009C>T p.H337Y | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs766070661, COSV100207502; called by muse, mutect2, varscan2
- COL12A1 | c.1411G>T p.E471* | Nonsense Mutation (SNP) | VAF 71/293 reads (24%) | catalogued as COSV100485766, COSV59408120; called by muse, mutect2, varscan2
- COL6A6 | c.2329T>A p.Y777N | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.413); catalogued as COSV100650150; called by muse, mutect2
- COLGALT1 | c.502G>C p.D168H | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99394952; called by muse, mutect2, varscan2
- CPAMD8 | c.610A>T p.R204W (on ENST00000651564; = p.R157W on NM_015692.5) | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99359227; called by muse, mutect2, varscan2
- CPB2 | c.1263G>T p.R421S | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.248); catalogued as COSV99473040; called by muse, mutect2
- CSMD1 | c.1714A>T p.N572Y (on ENST00000520002; = p.N571Y on NM_033225.6) | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100146536; called by muse, mutect2, varscan2
- CSMD3 | c.3889T>A p.Y1297N (on ENST00000297405 / NM_001363185.1; = p.Y1193N on NM_052900.3) | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99831139; called by muse, mutect2, varscan2
- CSMD3 | c.3888T>A p.I1296= (on ENST00000297405 / NM_001363185.1; = p.I1192= on NM_052900.3) | Splice Region (SNP) | VAF 11/77 reads (14%) | catalogued as COSV99831141; called by muse, mutect2, varscan2
- CTNND2 | c.920T>A p.L307Q | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100474934; called by muse, mutect2
- CUZD1 | c.1652-2A>T p.X551_splice | Splice Site (SNP) | VAF 16/61 reads (26%) | catalogued as COSV100158690; called by muse, mutect2, varscan2
- CWC22 | c.1181A>T p.N394I | Missense Mutation (SNP) | VAF 48/235 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99844148; called by muse, mutect2, varscan2
- CXCR3 | c.502G>A p.V168M | Missense Mutation (SNP) | VAF 56/226 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs1349979497, COSV65461872; called by muse, mutect2, varscan2
- DHX8 | c.1727A>T p.Q576L | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.491); catalogued as COSV99292092; called by muse, mutect2, varscan2
- DNAH10 | c.2273A>T p.Q758L (on ENST00000409039; = p.Q697L on NM_207437.3) | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV101292166; called by muse, mutect2, varscan2
- DNAH5 | c.12749A>T p.Q4250L | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as rs1285937528, COSV99448121; called by muse, mutect2, varscan2
- DNAH8 | c.1576C>T p.R526C | Missense Mutation (SNP) | VAF 63/227 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs753499080, COSV100544351; called by muse, mutect2, varscan2
- DOCK2 | c.4231G>A p.V1411I | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV99911515; called by muse, mutect2, varscan2
- DPYSL5 | c.85T>A p.Y29N | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99982166; called by muse, mutect2, varscan2
- DRD2 | c.155A>T p.N52I | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100669503; called by muse, mutect2, varscan2
- DROSHA | c.2140G>C p.V714L | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.119); catalogued as COSV100757570; called by muse, mutect2, varscan2
- DSE | c.2350A>T p.R784* | Nonsense Mutation (SNP) | VAF 31/142 reads (22%) | catalogued as COSV100528488; called by muse, mutect2, varscan2
- DTX4 | c.202C>G p.Q68E | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as COSV99915237; called by muse, mutect2, varscan2
- DUSP4 | c.755A>T p.K252M | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.995); catalogued as COSV99529763; called by muse, mutect2, varscan2
- EDDM3A | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.97); PolyPhen benign (0.08); catalogued as rs1051566021, COSV100473335; called by muse, mutect2, varscan2
- ELL2 | c.480A>T p.V160= | Splice Region (SNP) | VAF 18/68 reads (26%) | catalogued as rs762366919, COSV99427376; called by muse, mutect2, varscan2
- EML5 | c.4307A>T p.Q1436L (on ENST00000380664; = p.Q1444L on NM_183387.3) | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100715378; called by muse, mutect2, varscan2
- EPHA4 | c.901T>A p.W301R | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV99916204; called by muse, mutect2, varscan2
- ERBB3 | c.601G>T p.D201Y | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); catalogued as COSV99916509; called by muse, mutect2, varscan2
- EXOC7 | c.1550A>T p.Q517L (on ENST00000335146 / NM_001145297.4; = p.Q435L on NM_015219.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV100135107; called by muse, mutect2, varscan2
- EXOC7 | c.851A>T p.Q284L | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.098); catalogued as COSV100135111; called by muse, mutect2, varscan2
- EXTL3 | c.445A>T p.N149Y | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.926); catalogued as COSV99593926; called by muse, mutect2, varscan2
- FAM204A | c.662A>G p.K221R | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100977433; called by muse, mutect2, varscan2
- FAM83A | c.991T>C p.S331P | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99414192; called by muse, mutect2, varscan2
- FANCM | c.2759C>T p.P920L | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs776256629, COSV57505022, COSV99950887; called by muse, mutect2, varscan2
- FANCM | c.3053A>T p.E1018V | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.282); catalogued as COSV99950890; called by muse, mutect2, varscan2
- FAR1 | c.207A>T p.R69S | Missense Mutation (SNP) | VAF 69/309 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); catalogued as COSV100701545; called by muse, mutect2, varscan2
- FBXO45 | c.231G>C p.E77D | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0.005); catalogued as COSV100218052, COSV100218119; called by muse, mutect2, varscan2
- FERMT1 | c.1595T>A p.L532Q | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99451417; called by muse, mutect2, varscan2
- FGF14 | c.73T>C p.F25L | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs769648115, COSV101085625; called by muse, mutect2
- FLG | c.5498T>A p.V1833E | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.346); catalogued as COSV100911435; called by muse, mutect2, varscan2
- FNDC8 | c.412G>T p.G138C | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV50100619, COSV99338729; called by muse, mutect2, varscan2
- FOXN1 | c.916C>T p.P306S | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99881163; called by muse, mutect2, varscan2
- FOXN1 | c.1177G>C p.G393R | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1309137247, COSV99881164; called by muse, mutect2, varscan2
- FOXR1 | c.857T>A p.M286K | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.502); catalogued as COSV100392874, COSV57651321; called by muse, mutect2, varscan2
- FRZB | c.862-2A>T p.X288_splice | Splice Site (SNP) | VAF 28/71 reads (39%) | catalogued as COSV99717331; called by muse, mutect2, varscan2
- GAD1 | c.1171A>T p.N391Y | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.678); catalogued as rs1290731220, COSV100827924; called by muse, mutect2, varscan2
- GBA | c.559A>T p.S187C | Missense Mutation (SNP) | VAF 93/295 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV100516302; called by muse, mutect2, varscan2
- GGN | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as rs748092486, COSV99287403; called by muse, mutect2, varscan2
- GLI4 | c.1054G>T p.A352S | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as COSV100390989; called by muse, mutect2, varscan2
- GMPS | c.1363A>G p.I455V | Missense Mutation (SNP) | VAF 169/509 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99903058; called by muse, mutect2, varscan2
- GRIA4 | c.727-2A>T p.X243_splice | Splice Site (SNP) | VAF 33/158 reads (21%) | catalogued as COSV99230476; called by muse, mutect2, varscan2
- GSDMC | c.598G>C p.V200L | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.342); catalogued as COSV99415841; called by muse, mutect2, varscan2
- H2BC13 | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV100704358; called by muse, mutect2, varscan2
- H4C3 | c.49A>T p.K17* | Nonsense Mutation (SNP) | VAF 17/69 reads (25%) | catalogued as COSV100619515, COSV58090501; called by muse, mutect2, varscan2
- HAS1 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as COSV99708328; called by muse, mutect2, varscan2
- HELZ | c.570A>T p.Q190H | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV100698631; called by muse, mutect2, varscan2
- HSPA9 | c.1247C>T p.A416V | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated, low confidence (0.55); PolyPhen probably damaging (0.999); catalogued as COSV99785396; called by muse, mutect2, varscan2
- HTR1E | c.172A>T p.N58Y | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100541049; called by muse, mutect2, varscan2
- HUWE1 | c.3887A>T p.E1296V | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.061); catalogued as rs1556980171, COSV99471622; called by muse, mutect2, varscan2
- IDE | c.1061-2A>T p.X354_splice | Splice Site (SNP) | VAF 53/267 reads (20%) | catalogued as COSV99793923; called by muse, mutect2, varscan2
- IGSF10 | c.651T>A p.H217Q | Missense Mutation (SNP) | VAF 31/167 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56788787; called by muse, mutect2, varscan2
- IGSF3 | c.2737A>T p.S913C (on ENST00000369486 / NM_001007237.3; = p.S933C on NM_001542.4) | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.934); catalogued as COSV100604489; called by muse, mutect2, varscan2
- IL2RG | c.247A>T p.T83S | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as COSV99340143; called by muse, mutect2, varscan2
- IQCG | c.815A>T p.N272I | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV99502238; called by muse, mutect2, varscan2
- ITPR1 | c.3515A>T p.Y1172F (on ENST00000354582; = p.Y1157F on NM_002222.7) | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.615); catalogued as COSV100230663; called by muse, mutect2, varscan2
- KCNG4 | c.553A>T p.R185W | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV100376987; called by muse, mutect2, varscan2
- KCNJ2 | c.717A>T p.E239D | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs943311933, COSV99696316; called by muse, mutect2, varscan2
- KDM3B | c.3616A>T p.K1206* | Nonsense Mutation (SNP) | VAF 71/313 reads (23%) | catalogued as COSV100069411; called by muse, mutect2, varscan2
- KIF21B | c.698T>A p.L233Q | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV100144301; called by muse, mutect2, varscan2
- KLHL40 | c.1568T>A p.L523Q | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV99825440; called by muse, mutect2, varscan2
- KLHL7 | c.283A>T p.I95F (on ENST00000339077 / NM_001031710.3; = p.I47F on NM_018846.5) | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.337); catalogued as COSV100177946; called by muse, mutect2, varscan2
- KLK6 | c.164T>A p.L55Q | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100037669; called by muse, mutect2, varscan2
- KRT33B | c.28C>A p.L10M | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.039); catalogued as COSV99290563; called by muse, mutect2, varscan2
- KRT6A | c.1121T>A p.L374Q | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100416878; called by muse, mutect2, varscan2
- KRT81 | c.1432T>A p.C478S | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as COSV100576965; called by muse, mutect2, varscan2
- LAT2 | c.719C>A p.A240D | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV99305769; called by muse, mutect2, varscan2
- LENG8 | c.580A>T p.S194C | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as COSV100457341; called by muse, mutect2, varscan2
- LMAN2L | c.1019A>T p.Q340L | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.276); catalogued as rs1449172958, COSV99383262; called by muse, mutect2, varscan2
- LRPPRC | c.1575A>T p.L525F | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV99580379; called by muse, mutect2, varscan2
- LTN1 | c.1235T>G p.F412C | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV100797940; called by muse, mutect2, varscan2
- LY86 | c.129G>C p.Q43H | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV100040969, COSV57913265; called by muse, mutect2, varscan2
- M1AP | c.582T>A p.D194E | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99303930; called by muse, mutect2, varscan2
- MAGEC3 | c.53T>A p.L18Q | Missense Mutation (SNP) | VAF 48/217 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.432); catalogued as COSV100025202; called by muse, mutect2, varscan2
- MAOB | c.609T>A p.N203K | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100955996; called by muse, mutect2, varscan2
- MAP2 | c.3593A>T p.Q1198L | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.322); catalogued as COSV52293386, COSV99559192; called by muse, mutect2, varscan2
- METTL2B | c.1097A>T p.Q366L | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV99299771; called by muse, mutect2, varscan2
- MFAP5 | c.61T>A p.W21R | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as COSV100848125; called by muse, mutect2, varscan2
- MMP20 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99497602; called by muse, mutect2, varscan2
- MS4A14 | c.319-2A>T p.X107_splice | Splice Site (SNP) | VAF 15/85 reads (18%) | catalogued as COSV100280279; called by muse, mutect2, varscan2
- MS4A3 | c.147A>C p.Q49H | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99614665; called by muse, mutect2, varscan2
- MSH4 | c.2733A>G p.I911M | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99078927; called by muse, mutect2, varscan2
- NAALAD2 | c.1835T>A p.L612* | Nonsense Mutation (SNP) | VAF 25/123 reads (20%) | catalogued as COSV100428317; called by muse, mutect2, varscan2
- NBAS | c.6119C>T p.A2040V | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV55733493; called by muse, mutect2
- NBPF3 | c.736G>T p.E246* | Nonsense Mutation (SNP) | VAF 39/130 reads (30%) | catalogued as COSV100558597; called by muse, mutect2, varscan2
- NCR2 | c.487A>T p.R163* | Nonsense Mutation (SNP) | VAF 17/73 reads (23%) | catalogued as COSV100897209; called by muse, mutect2, varscan2
- NDUFA5 | c.149A>T p.Q50L | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); catalogued as COSV100864229; called by muse, mutect2, varscan2
- NFASC | c.216-2A>T p.X72_splice (on ENST00000339876 / NM_001378329.1; = p.X66_splice on NM_015090.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 22/81 reads (27%) | catalogued as COSV100363453; called by muse, mutect2, varscan2
- NFIC | c.377A>T p.K126M | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59413301; called by muse, mutect2, varscan2
- NLRP13 | c.2636T>A p.L879Q | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100738155; called by muse, mutect2, varscan2
- NOC3L | c.507A>T p.P169= | Splice Region (SNP) | VAF 23/122 reads (19%) | catalogued as COSV100993298; called by muse, mutect2, varscan2
- NPSR1 | c.1057T>G p.F353V | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.003); catalogued as COSV100706108, COSV62204592; called by muse, mutect2, varscan2
- NR2E1 | c.170A>T p.Q57L | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as COSV100934458; called by muse, mutect2, varscan2
- NTSR2 | c.1082T>A p.V361E | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as COSV100183868; called by muse, mutect2, varscan2
- OBSCN | c.15688A>T p.T5230S | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99476211; called by muse, mutect2, varscan2
- OPA1 | c.886A>T p.K296* (on ENST00000361510 / NM_130837.3; = p.K241* on NM_015560.3) | Nonsense Mutation (SNP) | VAF 83/322 reads (26%) | catalogued as COSV100655266; called by muse, mutect2, varscan2
- OPN4 | c.144A>C p.T48= | Splice Region (SNP) | VAF 12/58 reads (21%) | catalogued as COSV99618238; called by muse, mutect2, varscan2
- OR11H4 | c.368T>A p.L123H | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV100197469; called by muse, mutect2, varscan2
- OR1J1 | c.6C>A p.S2R | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs777428975, COSV99403120; called by muse, mutect2, varscan2
- OR2H1 | c.257C>A p.P86Q | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV65811810; called by muse, mutect2, varscan2
- OR2T12 | c.601T>A p.C201S | Missense Mutation (SNP) | VAF 162/477 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100527691; called by muse, mutect2, varscan2
- OR51E1 | c.760T>A p.Y254N | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV101211485; called by muse, mutect2, varscan2
- OR5D13 | c.158T>A p.L53H | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs1319343259, COSV100686824; called by muse, mutect2, varscan2
- OR7E24 | c.73A>T p.T25S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV101509650; called by muse, mutect2, varscan2
- PCDH18 | c.3098A>T p.N1033I | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as COSV100787217; called by muse, mutect2, varscan2
- PCDHA1 | c.123C>A p.H41Q | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV100974337; called by muse, mutect2, varscan2
- PCDHB6 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0.027); catalogued as COSV50700578; called by muse, mutect2, varscan2
- PCDHGA8 | c.914A>T p.K305I | Missense Mutation (SNP) | VAF 51/248 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.673); catalogued as COSV99535522; called by muse, mutect2, varscan2
- PCLO | c.11300A>T p.D3767V | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100430531; called by muse, mutect2, varscan2
- PDE11A | c.2624G>A p.S875N | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV53710487; called by muse, mutect2, varscan2
- PIGS | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.324); catalogued as COSV52023880; called by muse, mutect2, varscan2
- PKHD1L1 | c.2987A>T p.Q996L | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as COSV101005939; called by muse, mutect2, varscan2
- PLEK2 | c.106T>A p.Y36N | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99371714; called by muse, mutect2, varscan2
- PLXNA4 | c.4673G>A p.G1558E | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV100323692; called by muse, mutect2, varscan2
- PLXNB3 | c.5014G>T p.V1672L | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.103); catalogued as COSV100737302; called by muse, mutect2, varscan2
- PNISR | c.1414A>T p.R472* | Nonsense Mutation (SNP) | VAF 12/66 reads (18%) | catalogued as COSV100984338; called by muse, mutect2, varscan2
- PPP2CA | c.842C>A p.T281N | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51538744; called by muse, mutect2, varscan2
- PRSS58 | c.643T>A p.C215S | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV101616115; called by muse, mutect2, varscan2
- PTER | c.809A>G p.D270G | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.617); catalogued as COSV100126624; called by muse, mutect2, varscan2
- PTK2B | c.1414A>G p.M472V | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs748911697, COSV100593723; called by muse, mutect2, varscan2
- PTPN12 | c.1056A>C p.E352D | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV99950242; called by muse, mutect2, varscan2
- PTPRB | c.2386T>A p.Y796N | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99716872; called by muse, mutect2, varscan2
- PXDNL | c.1296A>C p.E432D | Missense Mutation (SNP) | VAF 58/243 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.823); catalogued as COSV100683037; called by muse, mutect2, varscan2
- QRICH1 | c.2084C>G p.P695R | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.94); catalogued as COSV100454998, COSV58708996; called by muse, varscan2
- R3HDML | c.251T>A p.M84K | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762149787, COSV99407084; called by muse, mutect2, varscan2
- RAG1 | c.256A>T p.K86* | Nonsense Mutation (SNP) | VAF 37/142 reads (26%) | catalogued as CD982919, COSV100200825; called by muse, mutect2, varscan2
- RAG2 | c.646A>T p.I216F | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV100271215; called by muse, mutect2, varscan2
- RALGDS | c.2007C>T p.S669= | Splice Region (SNP) | VAF 4/26 reads (15%) | catalogued as rs1290747642, COSV64426601; called by muse, mutect2
- RGS10 | c.354G>A p.M118I (on ENST00000369101; = p.M112I on NM_002925.3) | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.962); catalogued as COSV100962195; called by muse, mutect2, varscan2
- RIF1 | c.1682A>T p.Q561L | Missense Mutation (SNP) | VAF 103/406 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.205); catalogued as COSV99690407; called by muse, mutect2, varscan2
- RIMS1 | c.3008A>T p.H1003L | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99325775; called by muse, mutect2, varscan2
- RNF17 | c.1734G>T p.L578F | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99692825; called by muse, mutect2, varscan2
- RNF39 | c.983T>A p.L328Q | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as COSV99748265; called by muse, mutect2
- ROR2 | c.2032T>A p.Y678N | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100995725; called by muse, mutect2, varscan2
- RPAP2 | c.1712A>T p.Q571L | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.282); catalogued as COSV101528671; called by muse, mutect2, varscan2
- S100A7A | c.148A>T p.K50* | Nonsense Mutation (SNP) | VAF 117/319 reads (37%) | catalogued as COSV100241522; called by muse, mutect2, varscan2
- SAR1B | c.347A>C p.D116A | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV101284156; called by muse, mutect2, varscan2
- SCN3A | c.2450A>C p.Y817S | Missense Mutation (SNP) | VAF 66/281 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99326481; called by muse, mutect2, varscan2
- SDK1 | c.299-2A>T p.X100_splice | Splice Site (SNP) | VAF 30/122 reads (25%) | catalogued as COSV101269172; called by muse, mutect2, varscan2
- SEC23B | c.2085A>T p.Q695H | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.405); catalogued as COSV99357605; called by muse, mutect2, varscan2
- SEMG1 | c.946A>T p.S316C | Missense Mutation (SNP) | VAF 92/403 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.82); catalogued as COSV99725187; called by muse, mutect2, varscan2
- SEZ6L | c.1732A>T p.T578S | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.329); catalogued as COSV99961796; called by muse, mutect2, varscan2
- SKI | c.1745A>T p.Q582L | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV101049318; called by muse, mutect2, varscan2
- SLC17A8 | c.1519C>G p.Q507E | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100035407; called by muse, mutect2, varscan2
- SLC24A2 | c.586G>T p.V196L | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99646266; called by muse, mutect2, varscan2
- SLC45A1 | c.35A>T p.D12V | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.085); catalogued as COSV99238669; called by muse, mutect2, varscan2
- SLC4A1 | c.2683T>A p.F895I | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.063); catalogued as COSV99293226; called by muse, mutect2, varscan2
- SLC4A1 | c.1040A>T p.Y347F | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV52260606; called by muse, mutect2, varscan2
- SLC5A1 | c.984G>A p.M328I | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.019); catalogued as COSV99833341; called by muse, mutect2, varscan2
- SLC6A4 | c.323T>A p.I108K | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99911325; called by muse, mutect2, varscan2
- SLITRK1 | c.1786A>T p.S596C | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.106); catalogued as COSV100999901; called by muse, mutect2, varscan2
- SLU7 | c.1492A>T p.K498* | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | catalogued as COSV99775541; called by muse, mutect2
- SMCHD1 | c.5572A>T p.T1858S | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99861324; called by muse, mutect2, varscan2
- SPACA3 | c.335T>A p.L112Q | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99284154; called by muse, mutect2, varscan2
- SPICE1 | c.183A>T p.R61S | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99871205; called by muse, mutect2, varscan2
- ST18 | c.2591A>T p.Q864L | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV99389142; called by muse, mutect2, varscan2
- STK32C | c.1262A>G p.Y421C | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.865); catalogued as rs374006685; called by muse, mutect2, varscan2
- SULF1 | c.580T>A p.L194I | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.171); catalogued as COSV99482758; called by muse, mutect2, varscan2
- SYT3 | c.1316T>A p.L439H | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100143983; called by muse, mutect2, varscan2
- TAF2 | c.916A>T p.T306S | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.406); catalogued as rs1476157767, COSV100978583; called by muse, mutect2, varscan2
- TAGAP | c.884A>T p.H295L | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV100487365; called by muse, mutect2, varscan2
- TANC1 | c.4447G>T p.V1483F | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV99713585; called by muse, mutect2, varscan2
- TDRD6 | c.5821A>T p.R1941* | Nonsense Mutation (SNP) | VAF 56/226 reads (25%) | catalogued as COSV100287431; called by muse, mutect2, varscan2
- TEX11 | c.2675T>G p.L892R (on ENST00000344304; = p.L877R on NM_031276.3) | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100721543; called by muse, mutect2, varscan2
- TEX11 | c.766A>G p.K256E (on ENST00000344304; = p.K241E on NM_031276.3) | Missense Mutation (SNP) | VAF 114/586 reads (19%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.562); catalogued as COSV100721546; called by muse, mutect2, varscan2
- THBS3 | c.2696A>T p.Q899L | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as COSV100104112; called by muse, mutect2, varscan2
- THSD7B | c.4493A>T p.Y1498F (on ENST00000272643; = p.Y1496F on NM_001316349.2) | Missense Mutation (SNP) | VAF 59/238 reads (25%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as COSV55730481, COSV99748232; called by muse, mutect2, varscan2
- TMEM39A | c.856A>T p.K286* | Nonsense Mutation (SNP) | VAF 33/160 reads (21%) | catalogued as COSV100052355; called by muse, mutect2, varscan2
- TMPRSS15 | c.2306A>T p.H769L | Missense Mutation (SNP) | VAF 75/326 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.08); catalogued as COSV99517575; called by muse, mutect2, varscan2
- TNKS1BP1 | c.3874C>T p.P1292S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as rs1268813227, COSV100835949; called by muse, mutect2, varscan2
- TOMM22 | c.118-2A>T p.X40_splice | Splice Site (SNP) | VAF 13/56 reads (23%) | catalogued as COSV99320130; called by muse, mutect2, varscan2
- TRIM49 | c.325A>G p.S109G | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.464); catalogued as COSV100315985; called by muse, mutect2, varscan2
- TRPC7 | c.790A>T p.R264W | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.065); catalogued as COSV100725641; called by muse, mutect2, varscan2
- TSC2 | c.415A>T p.R139W | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CD993486, COSV99553587; called by muse, mutect2, varscan2
- TTN | c.90495T>C p.T30165= (on ENST00000591111; = p.T22741= on NM_003319.4) | Splice Region (SNP) | VAF 26/115 reads (23%) | catalogued as COSV100605118; called by muse, mutect2, varscan2
- UBAP2 | c.2420A>G p.N807S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV100671199; called by muse, mutect2, varscan2
- UBE3B | c.2851A>T p.R951* | Nonsense Mutation (SNP) | VAF 17/55 reads (31%) | catalogued as COSV100688663; called by muse, mutect2, varscan2
- UBXN7 | c.683T>C p.V228A | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV99581128; called by muse, mutect2, varscan2
- UGT2B17 | c.184A>T p.I62F | Missense Mutation (SNP) | VAF 99/209 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV100497199; called by muse, mutect2, varscan2
- UHRF1BP1L | c.1919A>T p.Y640F | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.015); catalogued as COSV99691414; called by muse, mutect2, varscan2
- WASHC4 | c.2361A>T p.R787S | Missense Mutation (SNP) | VAF 52/264 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100162347; called by muse, mutect2, varscan2
- WDR11 | c.2350A>C p.M784L | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.651); catalogued as COSV99676442; called by muse, mutect2, varscan2
- WDR76 | c.376A>T p.K126* | Nonsense Mutation (SNP) | VAF 31/87 reads (36%) | catalogued as COSV99776278; called by muse, mutect2, varscan2
- WDR91 | c.149A>T p.Q50L | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV100615659; called by muse, mutect2, varscan2
- WNT2 | c.256A>T p.N86Y | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99625938; called by muse, mutect2, varscan2
- ZBTB7C | c.712A>T p.K238* | Nonsense Mutation (SNP) | VAF 16/82 reads (20%) | catalogued as COSV100134351; called by muse, mutect2, varscan2
- ZFP14 | c.676A>T p.K226* | Nonsense Mutation (SNP) | VAF 20/70 reads (29%) | catalogued as COSV99525114; called by muse, mutect2, varscan2
- ZNF107 | c.328A>T p.S110C | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as COSV100788314; called by muse, mutect2, varscan2
- ZNF226 | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 11/68 reads (16%) | catalogued as COSV100335104, COSV56197859; called by muse, mutect2, varscan2
- ZNF407 | c.2411A>T p.Q804L | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.053); catalogued as COSV99995372; called by muse, mutect2, varscan2
- ZNF532 | c.3473C>T p.A1158V | Missense Mutation (SNP) | VAF 49/270 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as COSV100266323; called by muse, mutect2, varscan2
- ZNF619 | c.1376A>T p.Q459L | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV100123145; called by muse, mutect2, varscan2
- ZNF835 | c.100T>A p.C34S | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV101606318; called by muse, mutect2
- ZSWIM8 | c.1427G>T p.R476L | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV101289860; called by muse, mutect2, varscan2
- FAT2 | c.10384T>A p.Y3462N | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GRM3 | c.237dup p.N80Qfs*4 | Frame Shift Ins (INS) | VAF 27/121 reads (22%) | called by mutect2, pindel, varscan2
- H4C1 | c.160_203del p.E54* | Frame Shift Del (DEL) | VAF 18/161 reads (11%) | called by mutect2, pindel
- IGLV3-9 | c.137T>A p.I46N | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- KRT82 | c.569del p.L190Qfs*36 | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | called by mutect2, pindel, varscan2
- NDUFB3 | c.188_220del p.F63_G74delins* | Nonsense Mutation (DEL) | VAF 8/51 reads (16%) | called by mutect2, pindel
- NEK11 | c.855_866del p.Y286_E289del | In Frame Del (DEL) | VAF 36/202 reads (18%) | called by pindel, varscan2
- NEK11 | c.875A>C p.Q292P | Missense Mutation (SNP) | VAF 36/188 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.445); called by muse, varscan2
- OTOP1 | c.311T>A p.L104Q | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- SAGE1 | c.1165del p.T389Pfs*40 | Frame Shift Del (DEL) | VAF 29/159 reads (18%) | called by mutect2, pindel, varscan2
- TGFBR3 | c.2515del p.S839Afs*40 | Frame Shift Del (DEL) | VAF 5/23 reads (22%) | called by mutect2, varscan2
- ADAM33 | c.1455T>A p.P485= | Silent (SNP) | VAF 28/112 reads (25%) | catalogued as COSV100597804; called by muse, mutect2, varscan2
- ADCY8 | c.1986T>A p.S662= | Silent (SNP) | VAF 22/144 reads (15%) | catalogued as COSV99651652; called by muse, mutect2, varscan2
- ANKRD26 | c.4395A>T p.I1465= | Silent (SNP) | VAF 31/128 reads (24%) | catalogued as COSV101063106; called by muse, mutect2, varscan2
- ANKRD26 | c.1692A>T p.I564= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as COSV101063108; called by muse, mutect2, varscan2
- B4GALNT4 | c.2439A>T p.P813= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as COSV100327397; called by muse, mutect2, varscan2
- CBLC | c.1395G>T p.A465= | Silent (SNP) | VAF 29/155 reads (19%) | catalogued as rs1011305311, COSV99541962; called by muse, mutect2, varscan2
- CCDC150 | c.1194A>T p.A398= | Silent (SNP) | VAF 59/235 reads (25%) | catalogued as COSV99776769; called by muse, mutect2, varscan2
- CGN | c.2061A>G p.Q687= | Silent (SNP) | VAF 87/234 reads (37%) | catalogued as COSV99642176; called by muse, mutect2, varscan2
- CNTN1 | c.1878T>A p.R626= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV100751220; called by muse, mutect2, varscan2
- COBL | c.2868C>G p.G956= | Silent (SNP) | VAF 23/127 reads (18%) | catalogued as COSV99472161; called by muse, mutect2, varscan2
- COL1A2 | c.2646T>C p.R882= | Silent (SNP) | VAF 17/89 reads (19%) | catalogued as COSV99799292; called by muse, mutect2, varscan2
- COL9A1 | c.2394T>A p.P798= | Silent (SNP) | VAF 64/312 reads (21%) | catalogued as rs1253102068, COSV100294515, COSV57894268; called by muse, mutect2, varscan2
- CYP4F12 | c.702A>G p.K234= | Silent (SNP) | VAF 22/102 reads (22%) | catalogued as COSV100215760; called by muse, mutect2, varscan2
- DCX | c.609A>T p.T203= | Silent (SNP) | VAF 27/130 reads (21%) | catalogued as COSV100576349; called by muse, mutect2, varscan2
- DLL3 | c.1785A>T p.L595= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as COSV99219017; called by muse, mutect2, varscan2
- DSCAML1 | c.6066T>A p.A2022= (on ENST00000321322; = p.A1962= on NM_020693.4) | Silent (SNP) | VAF 22/116 reads (19%) | catalogued as COSV100355562; called by muse, mutect2, varscan2
- DSCAML1 | c.2250T>A p.P750= (on ENST00000321322; = p.P690= on NM_020693.4) | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV100355565; called by muse, mutect2, varscan2
- EFS | c.1194G>A p.P398= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as rs754723164, COSV53733434; called by muse, mutect2, varscan2
- EGF | c.1107T>A p.L369= | Silent (SNP) | VAF 28/103 reads (27%) | catalogued as COSV99490741; called by muse, mutect2, varscan2
- EXOC4 | c.2886C>A p.I962= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV99553331; called by muse, mutect2, varscan2
- EXOSC10 | c.1254A>G p.Q418= | Silent (SNP) | VAF 21/114 reads (18%) | catalogued as rs1277491208, COSV100442401; called by muse, mutect2, varscan2
- FAM9A | c.462T>A p.R154= | Silent (SNP) | VAF 56/224 reads (25%) | catalogued as COSV101121334; called by muse, mutect2, varscan2
- FBLN5 | c.336A>T p.I112= | Silent (SNP) | VAF 26/128 reads (20%) | catalogued as COSV99969502; called by muse, mutect2, varscan2
- FRMPD4 | c.2919T>A p.A973= | Silent (SNP) | VAF 61/223 reads (27%) | catalogued as COSV101042632; called by muse, mutect2, varscan2
- GNAT3 | c.246A>T p.L82= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV101242378; called by muse, mutect2, varscan2
- GRM4 | c.1935T>A p.A645= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV100946053; called by muse, mutect2, varscan2
- HGF | c.2109T>A p.P703= | Silent (SNP) | VAF 75/338 reads (22%) | catalogued as COSV99736458; called by muse, mutect2, varscan2
- HOXA10 | c.1074T>C p.N358= | Silent (SNP) | VAF 37/140 reads (26%) | catalogued as COSV52229355; called by muse, mutect2, varscan2
- ID1 | c.108T>C p.S36= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV101076714; called by muse, mutect2, varscan2
- IGKV1-16 | c.111A>T p.V37= | Silent (SNP) | VAF 47/170 reads (28%) | catalogued as rs184104299; called by muse, mutect2, varscan2
- IL17F | c.54G>A p.S18= | Silent (SNP) | VAF 25/123 reads (20%) | catalogued as rs772321235, COSV60233583; ClinVar: likely benign; called by muse, mutect2, varscan2
- IPO11 | c.2184T>G p.G728= | Silent (SNP) | VAF 38/187 reads (20%) | catalogued as COSV100320550; called by muse, mutect2, varscan2
- KCNH6 | c.2814T>A p.P938= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV100120940; called by muse, mutect2, varscan2
- KCNMA1 | c.106C>T p.L36= | Silent (SNP) | VAF 76/338 reads (22%) | catalogued as rs1446528365, COSV99696436; called by muse, varscan2
- KCNU1 | c.2352A>T p.G784= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV101299117; called by muse, mutect2, varscan2
- KERA | c.684A>T p.I228= | Silent (SNP) | VAF 31/104 reads (30%) | catalogued as COSV57130225, COSV99899385; called by muse, mutect2, varscan2
- KLC4 | c.1011A>T p.A337= | Silent (SNP) | VAF 36/147 reads (24%) | catalogued as COSV99431714; called by muse, mutect2, varscan2
- KLHL14 | c.441G>A p.V147= | Silent (SNP) | VAF 41/203 reads (20%) | catalogued as COSV100808870; called by muse, mutect2, varscan2
- LAMA1 | c.8085G>A p.R2695= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV101055898; called by muse, mutect2
- LAMA3 | c.3549A>T p.S1183= | Silent (SNP) | VAF 32/121 reads (26%) | catalogued as COSV100556348; called by muse, mutect2, varscan2
- LIMK1 | c.762C>T p.L254= | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as rs114886936; called by muse, mutect2, varscan2
- LLGL2 | c.1839C>T p.L613= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV99389455; called by muse, mutect2, varscan2
- LRRIQ1 | c.2718A>G p.E906= | Silent (SNP) | VAF 25/116 reads (22%) | catalogued as COSV101279989; called by muse, mutect2, varscan2
- MAGEB3 | c.804T>A p.P268= | Silent (SNP) | VAF 78/325 reads (24%) | catalogued as COSV100854658; called by muse, mutect2, varscan2
- MCEMP1 | c.417C>A p.G139= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as COSV100365350; called by muse, mutect2, varscan2
- MCPH1 | c.63A>T p.T21= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as COSV100765602; called by muse, mutect2, varscan2
- MMRN1 | c.2817A>T p.S939= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as COSV99306914; called by muse, mutect2, varscan2
- MRGPRX1 | c.660C>A p.L220= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV100245943, COSV57106045; called by muse, mutect2, varscan2
- MUC5B | c.10842C>A p.G3614= | Silent (SNP) | VAF 13/98 reads (13%) | catalogued as COSV101500236; called by muse, mutect2, varscan2
- MYLK3 | c.231G>A p.G77= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV101189100; called by muse, mutect2, varscan2
- MYOZ2 | c.231T>A p.S77= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as COSV100201621; called by muse, mutect2, varscan2
- N4BP2 | c.3084A>T p.I1028= | Silent (SNP) | VAF 80/300 reads (27%) | catalogued as COSV99788511; called by muse, mutect2, varscan2
- NEK4 | c.849T>C p.N283= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV99237506; called by muse, mutect2, varscan2
- NIPBL | c.6864G>A p.E2288= | Silent (SNP) | VAF 29/130 reads (22%) | catalogued as COSV99239441, COSV99239968; called by muse, mutect2, varscan2
- NLRP5 | c.453A>T p.P151= | Silent (SNP) | VAF 20/103 reads (19%) | catalogued as COSV101173549; called by muse, mutect2
- OLFML2B | c.1086C>T p.S362= | Silent (SNP) | VAF 22/130 reads (17%) | catalogued as rs768981145, COSV54201029; called by muse, mutect2, varscan2
- OR5T2 | c.447A>T p.T149= | Silent (SNP) | VAF 27/99 reads (27%) | catalogued as rs369632317, COSV100506896; called by muse, mutect2, varscan2
- PARD6B | c.507A>T p.L169= | Silent (SNP) | VAF 48/185 reads (26%) | catalogued as COSV100859904; called by muse, mutect2, varscan2
- PCDH11X | c.1665A>T p.T555= | Silent (SNP) | VAF 83/315 reads (26%) | catalogued as COSV100010845; called by muse, mutect2, varscan2
- PCDHA2 | c.1434A>T p.S478= | Silent (SNP) | VAF 35/173 reads (20%) | catalogued as COSV100973781; called by muse, mutect2, varscan2
- PCDHA6 | c.840T>A p.S280= | Silent (SNP) | VAF 106/456 reads (23%) | catalogued as COSV100972219; called by muse, mutect2, varscan2
- PCDHB5 | c.372A>T p.T124= | Silent (SNP) | VAF 36/143 reads (25%) | catalogued as COSV99167815; called by muse, mutect2, varscan2
- PCLO | c.3708A>T p.L1236= | Silent (SNP) | VAF 41/175 reads (23%) | catalogued as COSV100430534; called by muse, mutect2, varscan2
- PLA2R1 | c.1527T>A p.S509= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as COSV99322659; called by muse, mutect2, varscan2
- PLAAT5 | c.408T>A p.I136= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV100080449; called by muse, mutect2, varscan2
- PLCH1 | c.4872T>A p.P1624= (on ENST00000340059 / NM_001130960.2; = p.P1616= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 57/153 reads (37%) | catalogued as COSV100396351; called by muse, mutect2, varscan2
- POLQ | c.3096A>T p.S1032= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as COSV99952042; called by muse, mutect2, varscan2
- POTEE | c.627T>A p.A209= | Silent (SNP) | VAF 42/196 reads (21%) | catalogued as COSV100387572; called by muse, mutect2, varscan2
- PRRG1 | c.27A>G p.E9= | Silent (SNP) | VAF 145/644 reads (23%) | catalogued as COSV101068933; called by muse, mutect2, varscan2
- PTPRB | c.576T>A p.S192= | Silent (SNP) | VAF 18/98 reads (18%) | catalogued as COSV99716875; called by muse, mutect2, varscan2
- RALGAPA2 | c.1263T>A p.A421= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as COSV99173385; called by muse, mutect2, varscan2
- RNGTT | c.873A>T p.V291= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV99666155; called by muse, mutect2, varscan2
- ROR2 | c.876T>A p.P292= | Silent (SNP) | VAF 25/95 reads (26%) | catalogued as COSV100995726; called by muse, mutect2, varscan2
- SSH1 | c.1668G>A p.Q556= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV100425437; called by muse, mutect2, varscan2
- SSX1 | c.348A>T p.P116= | Silent (SNP) | VAF 105/489 reads (21%) | catalogued as COSV100976376; called by muse, mutect2, varscan2
- TENT5D | c.612T>G p.A204= | Silent (SNP) | VAF 70/283 reads (25%) | catalogued as COSV100382665; called by muse, mutect2, varscan2
- TGFB2 | c.774A>T p.T258= | Silent (SNP) | VAF 27/187 reads (14%) | catalogued as COSV100860034, COSV65110098; called by muse, mutect2, varscan2
- TMEM132B | c.2916A>T p.I972= | Silent (SNP) | VAF 38/113 reads (34%) | catalogued as COSV100169236; called by muse, mutect2, varscan2
- TNRC6B | c.4545A>T p.V1515= (on ENST00000454349 / NM_001162501.2; = p.V1405= on NM_015088.3) | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV100109428; called by muse, mutect2, varscan2
- TREML2 | c.552T>A p.P184= | Silent (SNP) | VAF 28/132 reads (21%) | catalogued as COSV101530162; called by muse, mutect2, varscan2
- TRO | c.3483T>C p.S1161= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as COSV99436189; called by muse, mutect2, varscan2
- TSPYL6 | c.123T>C p.D41= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV100336487; called by muse, mutect2, varscan2
- ZNF135 | c.27A>T p.T9= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as rs777966791, COSV100536560; called by muse, mutect2, varscan2
- ZNF75D | c.612T>C p.H204= | Silent (SNP) | VAF 43/171 reads (25%) | catalogued as COSV100883621; called by muse, mutect2, varscan2
- DCHS2 | n.7809A>T | RNA (SNP) | VAF 20/61 reads (33%) | catalogued as COSV100601537; called by muse, mutect2, varscan2
- DMD | c.1331+2655T>A | Intron (SNP) | VAF 69/238 reads (29%) | catalogued as COSV99921286; called by muse, mutect2, varscan2
- KIN | c.*1_*7del | 3'UTR (DEL) | VAF 9/47 reads (19%) | called by mutect2, pindel, varscan2
- MARCHF1 | c.-322-85477G>T | Intron (SNP) | VAF 24/69 reads (35%) | catalogued as COSV72282684; called by muse, mutect2
- MOCS2 | c.-99A>T | 5'UTR (SNP) | VAF 19/83 reads (23%) | catalogued as COSV100799013; called by muse, mutect2, varscan2
- RPGR | c.2520+1330A>T | Intron (SNP) | VAF 19/109 reads (17%) | catalogued as COSV100139859; called by muse, mutect2, varscan2
- ZNF702P | n.1792A>T | RNA (SNP) | VAF 61/294 reads (21%) | called by muse, mutect2, varscan2
